Somatic mutation profile of tumor specimen TCGA-DI-A1BY-01A (aliquot TCGA-DI-A1BY-01A-21D-A135-09) from TCGA case TCGA-DI-A1BY, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 63.3 years (23,113 days).
Specimen TCGA-DI-A1BY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc473e97-1352-4b8b-ab52-9a735ab3683b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DI-A1BY-10A (Blood Derived Normal), aliquot TCGA-DI-A1BY-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b458f055-c65b-42ff-9d3e-3f8b17e0779f

The open-access MAF lists 66 somatic variants for this specimen: 53 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 11, Nonsense Mutation 5, Frame Shift Ins 4, Frame Shift Del 2, 3'UTR 2, In Frame Del 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 16/66 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913413, COSV62688008, COSV62688560, COSV62714333; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 16/30 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.275A>T p.D92V | Missense Mutation (SNP) | VAF 17/63 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM132264, COSV64288500, COSV64301396, COSV64302611; called by muse, mutect2, varscan2
- AHNAK2 | c.13702G>A p.V4568I | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.199); catalogued as rs569250855, COSV60908182; called by muse, mutect2, varscan2
- AIFM3 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.364); catalogued as COSV100104816; called by muse, mutect2
- AQP6 | c.32G>A p.W11* | Nonsense Mutation (SNP) | VAF 21/60 reads (35%) | catalogued as COSV100210209; called by muse, mutect2, varscan2
- ARHGAP35 | c.1201C>T p.R401W | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs544976512, COSV101351334; called by muse, mutect2, varscan2
- ARID5B | c.1489del p.I497* | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as rs201178069; called by mutect2, pindel, varscan2
- C22orf23 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99317441; called by muse, mutect2, varscan2
- CD7 | c.183G>T p.Q61H | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV99486295; called by muse, mutect2, varscan2
- CDH17 | c.2426G>A p.R809H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.459); catalogued as rs201729274, COSV50327363; called by muse, mutect2, varscan2
- CEP95 | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.736); catalogued as rs544643355, COSV101616317; called by muse, mutect2, varscan2
- COL9A3 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs112769858, COSV100673501; called by muse, mutect2, varscan2
- CSPP1 | c.2179C>G p.P727A (on ENST00000676605; = p.P686A on NM_024790.6) | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.202); catalogued as COSV99139131; called by muse, mutect2, varscan2
- DGKB | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.811); catalogued as COSV99341481; called by muse, mutect2, varscan2
- DKK1 | c.348G>T p.K116N | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100906561; called by muse, mutect2, varscan2
- EIF5 | c.1091C>T p.S364F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99384942; called by muse, mutect2, varscan2
- FBN3 | c.7719_7720insA p.L2574Tfs*27 | Frame Shift Ins (INS) | VAF 18/56 reads (32%) | catalogued as COSV99561409; called by mutect2, pindel, varscan2
- GCLC | c.316T>C p.Y106H (on ENST00000643939; = p.Y110H on NM_001498.4) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99988773; called by muse, mutect2
- IRGQ | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs764250666, COSV60671701; called by muse, mutect2, varscan2
- KLHL1 | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 15/62 reads (24%) | catalogued as rs1206863431, COSV100917474, COSV64769679; called by muse, mutect2, varscan2
- KMT2D | c.11877G>T p.Q3959H | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.241); catalogued as COSV99984083; called by muse, mutect2, varscan2
- MYH6 | c.3575C>T p.A1192V | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as rs765797952, COSV100676803; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NDRG3 | c.977G>A p.R326Q (on ENST00000349004 / NM_032013.4; = p.R314Q on NM_022477.4) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs763972530, COSV100675421; called by muse, mutect2, varscan2
- OR12D2 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101011263; called by muse, mutect2, varscan2
- OTUD5 | c.1169A>G p.D390G | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99332136; called by muse, mutect2, varscan2
- OTUD7A | c.19C>A p.P7T | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.158); catalogued as COSV100192833; called by muse, mutect2, varscan2
- PCDHGA12 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV99341315; called by muse, mutect2, varscan2
- PCSK5 | c.1382C>T p.T461I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs748065478, COSV65086860; called by muse, mutect2, varscan2
- PKLR | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.146); catalogued as COSV100712968, COSV61360903; called by muse, mutect2, varscan2
- PLS3 | c.1789G>A p.G597R | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99171800; called by muse, mutect2, varscan2
- PTEN | c.723del p.F241Lfs*15 | Frame Shift Del (DEL) | VAF 26/92 reads (28%) | catalogued as COSV64288616, COSV64291647; called by mutect2, pindel, varscan2
- RACGAP1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs147422831; called by muse, mutect2, varscan2
- RAD51AP1 | c.446G>C p.S149T (on ENST00000228843 / NM_001130862.2; = p.S132T on NM_006479.5) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.501); catalogued as COSV57408666, COSV99961426; called by muse, mutect2, varscan2
- RNF133 | c.950T>C p.L317S | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100411674; called by muse, mutect2
- S100A8 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); catalogued as COSV64198043; called by muse, mutect2, varscan2
- SCN4A | c.2005C>T p.R669C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs897448432, COSV71125722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC8A1 | c.1379C>A p.T460N | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.938); catalogued as COSV100246837; called by muse, mutect2, varscan2
- TNIP3 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.36); catalogued as rs746782978, COSV50246703; called by muse, mutect2
- TTC31 | c.1228C>T p.R410* | Nonsense Mutation (SNP) | VAF 30/70 reads (43%) | catalogued as rs370957685; called by muse, mutect2, varscan2
- UBR1 | c.1379A>G p.N460S | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.475); catalogued as rs779007025, COSV99317565; called by muse, mutect2, varscan2
- UGCG | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 33/89 reads (37%) | catalogued as rs1419866026, COSV100958973; called by muse, mutect2, varscan2
- WDR25 | c.1364C>T p.T455I | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV100092045; called by muse, mutect2, varscan2
- ZIC3 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.06); catalogued as COSV99798724; called by muse, mutect2, varscan2
- ZNF804B | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as rs774321079, COSV60846037; called by muse, varscan2
- ARID1A | c.1882dup p.M628Nfs*14 | Frame Shift Ins (INS) | VAF 52/100 reads (52%) | called by mutect2, pindel, varscan2
- FCGBP | c.6816_6817insT p.D2273* | Frame Shift Ins (INS) | VAF 24/130 reads (18%) | called by mutect2, pindel, varscan2
- KDSR | c.622_624del p.N208del | In Frame Del (DEL) | VAF 21/50 reads (42%) | called by mutect2, pindel, varscan2
- KREMEN1 | c.110_115dup p.G37_A38dup (on ENST00000407188; = p.G39_A40dup on NM_032045.5) | In Frame Ins (INS) | VAF 13/44 reads (30%) | called by mutect2, varscan2
- SEC23A | c.1756_1758del p.R586del | In Frame Del (DEL) | VAF 6/35 reads (17%) | called by pindel, varscan2
- ZNF140 | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 79/200 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ZNF747 | c.102dup p.G35Rfs*44 | Frame Shift Ins (INS) | VAF 12/34 reads (35%) | called by mutect2, pindel, varscan2
- ABCA8 | c.384C>A p.T128= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV99286408; called by muse, mutect2, varscan2
- AFF2 | c.123C>T p.D41= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as rs782561675, COSV60656285; called by muse, mutect2, varscan2
- ATP1A2 | c.228C>T p.N76= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as rs201540165, COSV100768001, COSV63405167; called by muse, mutect2, varscan2
- CEP192 | c.2040G>C p.T680= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100381658, COSV58059925; called by muse, mutect2, varscan2
- DAG1 | c.1737C>T p.A579= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100445064, COSV100445240; called by muse, mutect2, varscan2
- GRIN1 | c.297C>T p.N99= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs1234541526, COSV59299548; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYCN | c.132C>T p.P44= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV99808419; called by muse, varscan2
- NEURL3 | c.480C>T p.D160= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100182463; called by muse, mutect2, varscan2
- NRXN2 | c.1962C>T p.Y654= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs757833579, COSV99635033; called by muse, mutect2, varscan2
- PRKCQ | c.1044T>G p.S348= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV99577366; called by muse, mutect2, varscan2
- ZBTB7A | c.327C>T p.S109= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV100475796; called by muse, mutect2, varscan2
- CABYR | c.*76G>A | 3'UTR (SNP) | VAF 27/81 reads (33%) | catalogued as rs751207486, COSV100112238; called by muse, mutect2, varscan2
- DNM1L | c.*1344C>T | 3'UTR (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99846293; called by muse, mutect2, varscan2
